CCDI case PBCANF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/69196047-4249-45c0-a054-756a7624f115

Demographics
Sex at birth: male; Race: black or african american; Vital status: Dead.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.9 years (6,182 days).

Biospecimens (3 samples)
- Sample 0DMN19: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMN1Q: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMN23: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
